Somatic mutation profile of tumor specimen TARGET-10-PARCLW-09A (aliquot TARGET-10-PARCLW-09A-01D) from TARGET case TARGET-10-PARCLW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,200 days).
Specimen TARGET-10-PARCLW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 456162da-0542-4cce-b144-706dba4b7068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCLW-10A (Blood Derived Normal), aliquot TARGET-10-PARCLW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f00e4b84-f16d-4283-b908-edf74d566eda

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Nonsense Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 46/117 reads (39%) | catalogued as rs142088943, COSV100417101; called by muse, mutect2, varscan2
- HTR5A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200887444; called by muse, mutect2, varscan2
- COL22A1 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- EWSR1 | c.1090T>A p.Y364N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FOLH1 | c.2182G>T p.V728L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- SHROOM4 | c.1253C>A p.A418E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC41A3 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TNXB | c.8254G>C p.E2752Q (on ENST00000647633; = p.E2505Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- FOXG1 | c.624C>T p.Y208= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs267606826, CM100363; called by muse, mutect2
- INSYN2A | c.1128C>A p.I376= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV54753275; called by muse, varscan2
- CCDC144CP | n.2473C>A | RNA (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- NR1H3 | c.*72A>T | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- PSMD1 | c.1239+91A>G | Intron (SNP) | VAF 15/28 reads (54%) | catalogued as rs904448128; called by muse, mutect2
